Somatic mutation profile of tumor specimen TCGA-DM-A1D4-01A (aliquot TCGA-DM-A1D4-01A-21D-A152-10) from TCGA case TCGA-DM-A1D4, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.5 years (29,403 days).
Specimen TCGA-DM-A1D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c9101fd-4659-42aa-a158-8402a5337a06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1D4-10A (Blood Derived Normal), aliquot TCGA-DM-A1D4-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/892c4ec1-472b-4940-a480-7101a06d0e3c

The open-access MAF lists 194 somatic variants for this specimen: 143 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 47, Nonsense Mutation 6, Frame Shift Ins 3, Splice Region 3, Frame Shift Del 3, Splice Site 2, Translation Start Site 2, RNA 1, Intron 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 50/72 reads (69%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 64/161 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 55/85 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 41/62 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12469A>T p.M4157L | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs774085026, COSV71289926; called by muse, mutect2, varscan2
- ADCYAP1 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as COSV52486826; called by muse, mutect2, varscan2
- ADGRB3 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101000638; called by muse, mutect2, varscan2
- ADNP2 | c.1026G>T p.Q342H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV51539764, COSV99031091; called by muse, mutect2, varscan2
- AFP | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99889962; called by muse, varscan2
- AGBL1 | c.3271T>A p.F1091I | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV66861306; called by muse, mutect2, varscan2
- AGER | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs17846806, COSV66719345; called by muse, mutect2, varscan2
- AJAP1 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs769421868, COSV65451311; called by muse, mutect2, varscan2
- ANKS1B | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773297608, COSV61357220; called by muse, mutect2, varscan2
- ASTN1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs751815220, COSV56064909; called by muse, mutect2, varscan2
- BSND | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100987627, COSV64871530; called by muse, mutect2, varscan2
- CACNA1E | c.6851G>A p.R2284Q (on ENST00000367573 / NM_001205293.3; = p.R2241Q on NM_000721.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as rs758954362, COSV62401204; called by muse, mutect2, varscan2
- CATSPERD | c.392-1G>T p.X131_splice | Splice Site (SNP) | VAF 51/149 reads (34%) | catalogued as COSV67535167; called by muse, mutect2, varscan2
- CCBE1 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67949959, COSV67950269; called by muse, mutect2, varscan2
- CDH2 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs199882009, COSV52274643; called by muse, mutect2, varscan2
- CHAMP1 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782149634, COSV63522582; called by muse, mutect2, varscan2
- CNOT6L | c.368G>A p.R123Q (on ENST00000504123 / NM_001286790.2; = p.R118Q on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as rs769058097, COSV53700912; called by muse, mutect2, varscan2
- COL5A2 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs149064715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.4934C>T p.P1645L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs764468586, COSV60390788; called by muse, mutect2, varscan2
- COQ7 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs772432536, COSV58982185; called by muse, varscan2
- CRYZL1 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51678100; called by muse, mutect2, varscan2
- CS | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs28389781, COSV57525077; called by muse, mutect2, varscan2
- CTNNB1 | c.2316T>A p.N772K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.041); catalogued as COSV100846221; called by muse, mutect2, varscan2
- DGKB | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 34/54 reads (63%) | catalogued as COSV51786707; called by muse, mutect2, varscan2
- DNAH5 | c.7634G>A p.R2545H | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs139348927, COSV54222169; called by muse, mutect2, varscan2
- DTX3L | c.902A>T p.N301I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56144560; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs112655288, COSV62568334; called by muse, mutect2, varscan2
- ENOX1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 115/202 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs757929801, COSV54903398; called by muse, mutect2, varscan2
- EPG5 | c.5743G>T p.G1915C | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56351201; called by muse, mutect2, varscan2
- EPHA10 | c.1835-2A>G p.X612_splice | Splice Site (SNP) | VAF 12/19 reads (63%) | catalogued as rs56091464, COSV57624701; called by muse, mutect2, varscan2
- ERCC6 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 188/451 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs150065567; called by muse, varscan2
- EXOSC8 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 101/201 reads (50%) | catalogued as rs778044271, COSV53509452; called by muse, mutect2, varscan2
- FAM153A | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 139/321 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs1485598537, COSV62362350; called by muse, mutect2, varscan2
- FAT3 | c.5935G>A p.G1979S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as rs778886701, COSV53125827; called by muse, mutect2, varscan2
- FBLN2 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs543602960, COSV55480693; called by muse, mutect2, varscan2
- FBXL2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs774933477, COSV52139667; called by muse, mutect2, varscan2
- FBXO4 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55852583; called by muse, mutect2, varscan2
- FCGR3A | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 78/135 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs778260076, COSV63459838; called by muse, mutect2, varscan2
- FSIP2 | c.16117G>T p.E5373* | Nonsense Mutation (SNP) | VAF 62/180 reads (34%) | catalogued as COSV58089216; called by muse, mutect2, varscan2
- FSTL5 | c.2125A>C p.I709L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV60201391; called by muse, mutect2, varscan2
- GPR12 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV67344032; called by muse, mutect2, varscan2
- GREB1 | c.3332C>T p.S1111L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs368967242, COSV52189094; called by muse, mutect2, varscan2
- GRIK5 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1370411751, COSV53480257; called by muse, mutect2, varscan2
- H2BC7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 50/140 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs747074252, COSV61911593; called by muse, mutect2, varscan2
- HARS1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as rs1131040, COSV56907390; called by muse, mutect2, varscan2
- HELZ | c.2248G>T p.A750S | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.18); catalogued as rs771979615, COSV62376155, COSV62379070; called by muse, mutect2, varscan2
- HLCS | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs373411061; called by muse, mutect2, varscan2
- HTR3B | c.992A>T p.Q331L | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV52745668; called by muse, mutect2, varscan2
- IFNB1 | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV66525503; called by muse, mutect2, varscan2
- IGHV3-20 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs782449916; called by muse, mutect2, varscan2
- ITPR1 | c.4157C>T p.T1386M (on ENST00000354582; = p.T1371M on NM_002222.7) | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231024; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1736C>A p.P579Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58022787; called by muse, mutect2, varscan2
- KCNG4 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as rs372954474; called by muse, mutect2, varscan2
- KMT2A | c.1442G>A p.S481N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV63287392; called by muse, mutect2, varscan2
- KRT33A | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs148488457; called by muse, mutect2, varscan2
- L3MBTL2 | c.1930G>A p.G644R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53433804; called by muse, mutect2, varscan2
- LAMA1 | c.6913G>T p.D2305Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67535428, COSV67538956; called by muse, mutect2, varscan2
- LRFN5 | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1223421354, COSV53250964; called by muse, mutect2, varscan2
- LRRTM4 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 69/189 reads (37%) | catalogued as rs377112975; called by muse, mutect2, varscan2
- MAPK12 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs1307517554, COSV53133621; called by muse, mutect2, varscan2
- MAPT | c.827C>T p.P276L (on ENST00000262410 / NM_001377265.1; = p.P201L on NM_016835.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); catalogued as COSV52241651; called by muse, mutect2, varscan2
- MMS22L | c.3312C>A p.N1104K | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV51522184; called by muse, mutect2, varscan2
- MTA1 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs200007908; called by muse, mutect2, varscan2
- MUC16 | c.26422A>G p.S8808G | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV67473620, COSV99064292; called by muse, mutect2, varscan2
- MYH14 | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs368918699, COSV51821340; called by muse, mutect2, varscan2
- NDRG1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs963190299, COSV60484389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEFM | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV55332868; called by muse, mutect2, varscan2
- NFASC | c.2684G>A p.R895H (on ENST00000339876 / NM_001378329.1; = p.R998H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as rs771159287, COSV58358643; called by muse, mutect2, varscan2
- NOD1 | c.1025T>C p.F342S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV56111743, COSV56113071; called by muse, mutect2, varscan2
- NPHS1 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as rs200905486, CM016007, COSV100799833, COSV62289502; called by muse, mutect2, varscan2
- NUP210 | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV54407993; called by muse, mutect2, varscan2
- NUP54 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.086); catalogued as rs749764062, COSV53576085; called by muse, mutect2, varscan2
- NYAP2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754105472, COSV56007997; called by muse, mutect2, varscan2
- OR10H3 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs769130878, COSV59944141; called by muse, mutect2, varscan2
- OR5C1 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs371002896; called by muse, mutect2, varscan2
- PAPPA2 | c.4037C>T p.S1346L | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1453407973, COSV62790237; called by muse, mutect2, varscan2
- PCDH15 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs771976717, COSV57330685; called by muse, mutect2, varscan2
- PCDHGA7 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.187); catalogued as COSV53967474; called by muse, mutect2, varscan2
- PCLO | c.2779G>A p.V927M | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs765996457, COSV61642025, COSV61650906; called by muse, mutect2, varscan2
- PDZD8 | c.3109G>C p.E1037Q | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53691265; called by muse, mutect2, varscan2
- PER2 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs199703220, COSV54524653; called by muse, mutect2, varscan2
- PEX16 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767624302, COSV53802399; called by muse, mutect2, varscan2
- PLPPR1 | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66454241; called by muse, mutect2, varscan2
- POLQ | c.5171A>C p.K1724T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.915); catalogued as COSV99952214; called by muse, mutect2, varscan2
- POTEH | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 180/745 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as rs570485286, COSV58880603, COSV58880705, COSV58883759; called by muse, mutect2, varscan2
- PPFIA2 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV61036838; called by muse, mutect2, varscan2
- PRAM1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as rs909084826, COSV55314355; called by muse, mutect2, varscan2
- PROS1 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs780863931, CM041822, COSV67775511; called by muse, mutect2, varscan2
- PSG6 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as rs370061837; called by muse, mutect2, varscan2
- PYGL | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs889803313, COSV53586566; called by muse, mutect2, varscan2
- RELN | c.3457G>T p.V1153F | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV100633643; called by muse, mutect2, varscan2
- RETREG3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1372884046, COSV58703061; called by muse, mutect2, varscan2
- RND2 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV56816485; called by muse, mutect2, varscan2
- RNF217 | c.1352G>A p.R451Q (on ENST00000521654 / NM_001286398.2; = p.R159Q on NM_152553.5) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs778499520, COSV51575465; called by muse, mutect2, varscan2
- RPS6KA5 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | catalogued as COSV56222730; called by muse, mutect2, varscan2
- RPUSD4 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs778701900, COSV53599458; called by muse, mutect2, varscan2
- RYR1 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1364757414, COSV100615646, COSV62089865; called by muse, mutect2, varscan2
- SCARA5 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs775439485, COSV57278189; called by muse, mutect2, varscan2
- SCN1A | c.2548G>A p.A850T (on ENST00000303395 / NM_001202435.3; = p.A839T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs757616558, COSV100320463, COSV57682879; called by muse, mutect2, varscan2
- SLC39A6 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs778520944, COSV52369713; called by muse, mutect2, varscan2
- SLC6A1 | c.372C>T p.G124= | Splice Region (SNP) | VAF 44/113 reads (39%) | catalogued as rs759369840, COSV55114817; called by muse, mutect2, varscan2
- SLF1 | c.2821G>A p.A941T | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV54370736; called by muse, mutect2, varscan2
- SMPD2 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV57805858; called by muse, mutect2, varscan2
- SNF8 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV51726924; called by muse, mutect2, varscan2
- SPEG | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs759418830, COSV56663544; called by muse, mutect2, varscan2
- STAB1 | c.3608G>A p.R1203Q | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs762496483, COSV58732236; called by muse, mutect2, varscan2
- STK31 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100669359; called by muse, mutect2, varscan2
- TAF1L | c.4614G>T p.M1538I | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as rs1407479141, COSV54263562; called by muse, mutect2, varscan2
- TEK | c.3307G>A p.V1103M | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66229718; called by muse, mutect2, varscan2
- TENM2 | c.5387C>T p.A1796V (on ENST00000518659 / NM_001122679.2; = p.A1557V on NM_001080428.3) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs748948614, COSV69133258; called by muse, mutect2, varscan2
- TENM4 | c.5488C>T p.R1830W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1250643833, COSV53605049; called by muse, mutect2, varscan2
- THEMIS | c.1910A>G p.E637G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV64071836; called by muse, mutect2, varscan2
- THEMIS | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64071842; called by muse, mutect2, varscan2
- TIMP2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs775066324, COSV53161314; called by muse, mutect2, varscan2
- TLL2 | c.629G>T p.R210I | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV63573229; called by muse, mutect2, varscan2
- TMEM87B | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as COSV51715925; called by muse, mutect2, varscan2
- TNN | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV53421489; called by muse, mutect2, varscan2
- TRIM54 | c.568G>A p.A190T (on ENST00000380075 / NM_187841.3; = p.A232T on NM_032546.4) | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV51990835; called by muse, varscan2
- TRIM60 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as rs772964136, COSV61970273; called by muse, mutect2, varscan2
- TSKS | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs199829146; called by muse, mutect2, varscan2
- TTLL1 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56739094; called by muse, mutect2, varscan2
- TUBA4A | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99944771; called by muse, mutect2, varscan2
- UBLCP1 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57142799, COSV57143657; called by muse, mutect2, varscan2
- VLDLR | c.1805C>A p.P602H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101173224; called by muse, mutect2, varscan2
- WDFY1 | c.1065T>C p.D355= | Splice Region (SNP) | VAF 18/32 reads (56%) | catalogued as COSV51790389; called by muse, mutect2, varscan2
- ZFP3 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs763913364, COSV59583242; called by muse, mutect2, varscan2
- ZNF273 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV100139304; called by muse, mutect2, varscan2
- ZNF615 | c.1595G>T p.R532L | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV65032289, COSV65033860; called by muse, mutect2, varscan2
- ZNF646 | c.625A>G p.N209D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs1410250259, COSV56215487; called by muse, mutect2, varscan2
- ZNF772 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs760858203, COSV58410722; called by muse, mutect2, varscan2
- ZNF813 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs199907213; called by muse, mutect2, varscan2
- APC | c.1081_1082del p.H361Wfs*3 | Frame Shift Del (DEL) | VAF 35/71 reads (49%) | called by mutect2, pindel, varscan2
- CSAG3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 150/403 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- FAM71D | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FAT4 | c.10169del p.E3390Gfs*4 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | called by mutect2, pindel*
- MUC16 | c.23902dup p.T7968Nfs*2 | Frame Shift Ins (INS) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
- SMAD4 | c.455-2_455-1dup | Splice Region (INS) | VAF 21/38 reads (55%) | called by mutect2, pindel, varscan2
- TFPI | c.755dup p.N253Kfs*2 | Frame Shift Ins (INS) | VAF 42/127 reads (33%) | called by mutect2, pindel, varscan2
- TIMP3 | c.602del p.P201Rfs*26 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- ANK2 | c.4236T>C p.P1412= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs1322739745, COSV100001527; called by muse, mutect2, varscan2
- ANKRD36 | c.411C>T p.Y137= | Silent (SNP) | VAF 305/791 reads (39%) | catalogued as rs940058480, COSV70739959; called by muse, mutect2, varscan2
- ANO2 | c.1473A>C p.R491= (on ENST00000356134 / NM_001278597.3; = p.R495= on NM_001278596.3) | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV59027991; called by muse, mutect2, varscan2
- CA8 | c.300G>A p.S100= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs749173414, COSV100526643, COSV58772456; called by muse, mutect2, varscan2
- CACNA1E | c.5610A>C p.A1870= | Silent (SNP) | VAF 82/150 reads (55%) | catalogued as COSV62401189; called by muse, mutect2, varscan2
- CALHM1 | c.702G>A p.T234= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs760942799, COSV53296260; called by muse, mutect2, varscan2
- CHST11 | c.474C>T p.S158= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs750754971, COSV57989268; called by muse, mutect2, varscan2
- CNTNAP2 | c.2698C>A p.R900= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs375318010, COSV62157895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL23A1 | c.1428G>A p.E476= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV66792116; called by muse, mutect2, varscan2
- CPA5 | c.801C>G p.G267= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV62569889; called by muse, mutect2, varscan2
- DBH | c.1083C>T p.N361= | Silent (SNP) | VAF 26/31 reads (84%) | catalogued as rs201759717, COSV55040528; called by muse, mutect2, varscan2
- DSPP | c.2526C>T p.S842= | Silent (SNP) | VAF 92/228 reads (40%) | catalogued as rs899663071; called by muse, mutect2, varscan2
- FOXD4L4 | c.204G>A p.A68= | Silent (SNP) | VAF 35/348 reads (10%) | called by muse, mutect2
- FOXD4L5 | c.204G>A p.A68= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs762262426, COSV101072986; called by muse, mutect2, varscan2
- GCM2 | c.951C>T p.Y317= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as COSV65275841; called by muse, mutect2, varscan2
- GIMAP8 | c.1893C>T p.S631= | Silent (SNP) | VAF 73/221 reads (33%) | catalogued as rs768595309, COSV100217522; called by muse, mutect2, varscan2
- GLRB | c.882G>A p.A294= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs376097077; called by muse, mutect2, varscan2
- GRIN2A | c.4041T>G p.G1347= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100409710; called by muse, mutect2, varscan2
- IRAG1 | c.975C>G p.P325= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as COSV70211600; called by muse, mutect2, varscan2
- KLC1 | c.477C>T p.D159= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs762809618, COSV55809710; called by muse, mutect2, varscan2
- KLF9 | c.618G>A p.P206= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs764995654, COSV65807813; called by muse, mutect2, varscan2
- LAMA1 | c.5289G>A p.A1763= | Silent (SNP) | VAF 75/111 reads (68%) | catalogued as rs761188683, COSV67536560; called by muse, mutect2, varscan2
- LMX1A | c.555T>C p.T185= | Silent (SNP) | VAF 105/200 reads (53%) | catalogued as COSV54220942, COSV54222735; called by muse, mutect2, varscan2
- MYO9B | c.3324G>A p.R1108= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV68280067; called by muse, mutect2, varscan2
- NIBAN3 | c.1506G>A p.Q502= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV56310289; called by muse, mutect2, varscan2
- NLRP5 | c.1161G>A p.P387= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs753433376, COSV66765416; called by muse, mutect2, varscan2
- NUP88 | c.135G>A p.S45= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as rs1011418018, COSV56706086; called by muse, mutect2, varscan2
- OOEP | c.291C>T p.F97= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs1370736514, COSV64859312; called by muse, mutect2, varscan2
- OTOA | c.1131G>A p.Q377= (on ENST00000286149; = p.Q363= on NM_144672.4) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV53756914; called by muse, mutect2, varscan2
- PCDHB9 | c.1659C>T p.D553= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs782620517, COSV53382558; called by muse, mutect2, varscan2
- PDE1C | c.120G>A p.T40= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as rs201079568; called by muse, mutect2, varscan2
- PPEF1 | c.1203G>A p.R401= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- PROKR1 | c.729C>A p.G243= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs1411582575, COSV100375237, COSV58137916; called by muse, mutect2, varscan2
- PTH2R | c.1398G>A p.A466= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs755036202, COSV55916958, COSV55920308; called by muse, mutect2, varscan2
- PTPRT | c.3564T>C p.R1188= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100627174, COSV62014944; called by mutect2, varscan2
- ROBO2 | c.3669C>T p.D1223= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs2272164, COSV59901154; called by muse, mutect2, varscan2
- RP1 | c.2511A>G p.Q837= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs753558619, COSV55119088; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD9 | c.2373C>T p.Y791= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs189020649, COSV66076095; called by muse, mutect2, varscan2
- SLC5A11 | c.624G>A p.T208= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs925120602, COSV61741019, COSV61742143; called by muse, mutect2, varscan2
- SLITRK1 | c.573G>A p.T191= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as rs370310778; called by muse, mutect2, varscan2
- SORCS2 | c.747C>T p.F249= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs981960074, COSV61172547; called by muse, mutect2, varscan2
- SOX11 | c.1119G>A p.A373= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs753364674, COSV58985970; called by muse, mutect2, varscan2
- TMOD1 | c.555A>G p.E185= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV52248846; called by muse, mutect2, varscan2
- TNXB | c.10485C>T p.T3495= (on ENST00000647633; = p.T3248= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1239982151, COSV64478180; called by muse, mutect2, varscan2
- TRO | c.1572G>C p.L524= | Silent (SNP) | VAF 80/97 reads (82%) | catalogued as COSV51502916, COSV99436321; called by muse, mutect2, varscan2
- TTN | c.75981C>A p.I25327= (on ENST00000591111; = p.I17903= on NM_003319.4) | Silent (SNP) | VAF 136/335 reads (41%) | catalogued as COSV60131786, COSV60175865; called by muse, mutect2, varscan2
- UNC79 | c.4608G>A p.A1536= (on ENST00000393151 / NM_001346218.2; = p.A1359= on NM_020818.5) | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs775349191, COSV56393074; called by muse, mutect2, varscan2
- DCHS2 | n.25C>A | RNA (SNP) | VAF 35/114 reads (31%) | catalogued as COSV100251753; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472241 C>A | 3'Flank (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- SUN1 | c.659-1499C>T | Intron (SNP) | VAF 277/489 reads (57%) | catalogued as rs752516583, COSV61779363; called by muse, mutect2, varscan2
- VPS11 | c.-430G>A | 5'UTR (SNP) | VAF 22/55 reads (40%) | catalogued as rs781978714, COSV100333741; called by muse, mutect2, varscan2
